Somatic mutation profile of tumor specimen MP2PRT-PAVHZP-TMP1-A (aliquot MP2PRT-PAVHZP-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVHZP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,522 days).
Specimen MP2PRT-PAVHZP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9022d66-ca02-42aa-91c8-83a4bc0b1787.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHZP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHZP-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8030b58e-a686-4b35-a21d-635f2bfbb516

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCT8L2 | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 54/475 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as rs777035647; called by muse, mutect2, varscan2
- FLT3 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 31/488 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1044875315, COSV54054856, COSV54072015, COSV54075214; called by muse, mutect2
- OR5M3 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV56566239; called by muse, mutect2, varscan2
- TRAPPC12 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 153/615 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.138); catalogued as rs753417333, COSV60848448; called by muse, mutect2, varscan2
- CPE | c.1261C>T p.L421F | Missense Mutation (SNP) | VAF 14/524 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.397); called by muse, mutect2
- RUBCN | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 174/497 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- RYR1 | c.10091G>A p.R3364Q | Missense Mutation (SNP) | VAF 26/570 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- DAGLA | c.2262G>A p.P754= | Silent (SNP) | VAF 71/608 reads (12%) | catalogued as rs770793670; called by muse, mutect2, varscan2
- FOXP2 | c.975T>C p.S325= | Silent (SNP) | VAF 22/289 reads (8%) | called by muse, mutect2
